EXCEPTIONAL_RESPONDERS case ER-B1HR — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9bfb5ec7-6fe1-443a-9eb2-75321b0da84a

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Year of birth: 1976; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma multiforme: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 28.9 years (10,570 days); Year of diagnosis: 2005; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 4,017 days (11.0 years); Days to best overall response: 448 days (1.2 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Temozolomide; Days to treatment start: 112 days; Days to treatment end: 494 days (1.4 years).

Follow-up (1 entry)
- Days to follow up: 4,017 days (11.0 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 4,017 days (11.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B1HR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B1HR-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
